Gene-level copy-number profile of tumor specimen C3N-00150-02 from CPTAC case C3N-00150, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.5 years (20,286 days).
Specimen C3N-00150-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4a3d30ac-97cf-45e8-b764-18b1958aa911.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00150-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/1090e753-a97b-463e-92cf-b77bc5ef0548

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 5; copy number 2: 2,889; copy number 4: 54,917; copy number 5: 514; copy number 6: 33; copy number 7: 10; copy number 8: 1; copy number 10: 11; copy number 37: 2.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,384,059–75,395,536, 3 genes: AC139453.2, LSP1P2, AC139453.1.
- chr3:75,540,049–75,599,673, 4 genes (within-gene range 0–13): AC133041.1, RPS3AP15, AC108724.1, OR7E121P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 10 (within-gene range 6–10): AL627309.1.
- chr1:131,025–195,411, 10 genes, copy number 10: CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr1:143,498,785–143,500,512, 2 genes, copy number 37: AC239859.2, LINC02799.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
